CCDI case PBCJBB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5ef2924c-cc7a-43db-b723-de6446b85e2f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.5 years (1,651 days).

Biospecimens (3 samples)
- Sample 0DT694: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT69B: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DT69F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
